Surgical pathology report (de-identified scan), TCGA case TCGA-CW-6096, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-CW-6096-01A (Primary Tumor).

Patient Identifier: [REDACTED]

[REDACTED] Surgical Pathology [REDACTED]

TISSUE DESCRIPTION:

Portion right kidney (13.3 grams, 3.8 x 2.9 x 2.7 cm).

DIAGNOSIS:

Kidney, right, partial nephrectomy: Grade 2 (of 4) renal cell carcinoma, clear cell type, forms a 2.5 x 2.2 x 2.1 cm mass. The tumor is confined to the kidney. Coagulative tumor necrosis is absent. Sarcomatoid differentiation is absent. The surgical margins are negative by 0.1 cm.

Source: NCI Genomic Data Commons file 4db4f358-8818-4f89-bba2-45e527af25f4 (TCGA-CW-6096.887F03C0-B5AD-4370-9797-9804900A952C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).